Somatic mutation profile of cancer-model specimen HCM-WCMC-0494-C16-85A (3D Organoid, passage 14; aliquot HCM-WCMC-0494-C16-85A-01D-A83U-36), derived from the primary tumor of HCMI case HCM-WCMC-0494-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 64.9 years (23,717 days).
Specimen HCM-WCMC-0494-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 14.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07e00a3a-4e39-444a-9f5a-1f162c584dfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0494-C16-10B (Blood Derived Normal), aliquot HCM-WCMC-0494-C16-10B-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be0d9d94-de42-45ec-8799-e09d9775d2c6

The open-access MAF lists 2,107 somatic variants for this specimen: 1,506 protein-altering or splice-affecting, 518 silent, 83 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,154, Silent 518, Frame Shift Del 194, Frame Shift Ins 58, Nonsense Mutation 53, Intron 43, 3'UTR 21, Splice Region 17, Splice Site 14, In Frame Del 12, 5'Flank 7, 5'UTR 5.

Variants (750 of 2,107; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 307/657 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs67561842, CM014485; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 142/335 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs760889253, COSV53970571; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AK2 | c.372+1G>A p.X124_splice (on ENST00000354858; = p.X166_splice on NM_001625.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 73/179 reads (41%) | catalogued as rs777503956, CS090016, COSV61468163; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP5Z1 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 157/331 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs761451474, COSV62241021, COSV62243859; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 256/534 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as rs1057523568, COSV61391392; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.9023G>A p.R3008H | Missense Mutation (SNP) | VAF 198/436 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587781894, CM092589, COSV53726175, COSV53741856; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GALNT3 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 62/307 reads (20%) | catalogued as rs775341386; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 170/358 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 290/658 reads (44%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LARS2 | c.*276C>T | 3'UTR (SNP) | VAF 162/324 reads (50%) | catalogued as rs398123036, CM132510, COSV55527677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 148/296 reads (50%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NECTIN4 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs267606991, CS105114; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1738dup p.Y580Lfs*8 | Frame Shift Ins (INS) | VAF 109/260 reads (42%) | catalogued as rs786204255; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NOTCH3 | c.6692dup p.A2233Gfs*9 | Frame Shift Ins (INS) | VAF 366/885 reads (41%) | catalogued as rs773656789; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PHYH | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 60/640 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894173, CM001297, COSV53816696; ClinVar: pathogenic; called by muse, mutect2
- RPE65 | c.1067del p.N356Mfs*17 | Frame Shift Del (DEL) | VAF 104/247 reads (42%) | catalogued as rs281865520, CD972436; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- RYR1 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 34/510 reads (7%) | catalogued as rs1346649518; ClinVar: pathogenic; called by muse, mutect2
- SPG11 | c.3075del p.E1026Sfs*12 | Frame Shift Del (DEL) | VAF 46/198 reads (23%) | catalogued as rs312262752; ClinVar: pathogenic; called by mutect2, varscan2
- TGFBR2 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 299/611 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893815, CM050762, CM159806, COSV55442586, COSV55450248; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRPM1 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 356/758 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906862, CM101525, COSV56632671; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.712C>A p.L238I | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs140764220; called by muse, mutect2, varscan2
- AAR2 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 253/515 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760715549; called by muse, mutect2, varscan2
- ABAT | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 267/578 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762137050, COSV51621604; called by muse, mutect2, varscan2
- ABCB9 | c.2050G>A p.A684T (on ENST00000280560 / NM_019625.4; = p.A641T on NM_019624.3) | Missense Mutation (SNP) | VAF 77/445 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs963513372; called by muse, mutect2, varscan2
- ABCC10 | c.3853G>A p.G1285S (on ENST00000372530 / NM_001198934.2; = p.G1257S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 270/624 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752598583, COSV55090909; called by muse, mutect2, varscan2
- ABCC6 | c.3892G>A p.V1298I | Missense Mutation (SNP) | VAF 224/532 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs63751325, CM014492; called by muse, mutect2, varscan2
- ABCC9 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 140/274 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs749786076, COSV53966945; called by muse, varscan2
- ABHD18 | c.959G>A p.R320H (on ENST00000398965 / NM_001039717.2; = p.R227H on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 204/408 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs368434647; called by muse, mutect2, varscan2
- ABLIM1 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 196/439 reads (45%) | catalogued as rs749527326; called by muse, mutect2, varscan2
- ABTB2 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 98/564 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs774571777; called by muse, mutect2, varscan2
- AC004593.2 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 61/335 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99765372; called by muse, mutect2, varscan2
- AC013489.1 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 257/545 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1567056827; called by muse, mutect2, varscan2
- AC093512.2 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 264/514 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.897); catalogued as rs1355782850; called by muse, mutect2, varscan2
- AC099489.1 | c.5161G>A p.G1721R | Missense Mutation (SNP) | VAF 144/316 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs576621414; called by muse, mutect2, varscan2
- AC099489.1 | c.4237G>A p.A1413T | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs777140143; called by muse, mutect2, varscan2
- ACAA1 | c.1219A>G p.M407V | Missense Mutation (SNP) | VAF 62/386 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1474235864; called by muse, mutect2, varscan2
- ACACB | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 265/550 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487182342; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 58/223 reads (26%) | catalogued as rs757016425; called by mutect2, varscan2
- ACLY | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 131/282 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1555632516, COSV100709834; called by muse, mutect2, varscan2
- ACSM2A | c.1098G>A p.T366= (on ENST00000219054; = p.T287= on NM_001308169.2) | Splice Region (SNP) | VAF 73/145 reads (50%) | catalogued as rs759143815, COSV54590075; called by muse, mutect2, varscan2
- ACSS3 | c.1590A>T p.K530N | Missense Mutation (SNP) | VAF 88/212 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV54098497; called by muse, mutect2, varscan2
- ACTR1A | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 50/642 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs1360371362, COSV64023074; called by muse, mutect2
- ACTR3C | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 102/231 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.191); catalogued as COSV99336820; called by muse, mutect2, varscan2
- ACTR8 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 244/529 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749439312; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 136/294 reads (46%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVRL1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 243/524 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as rs746430008; called by muse, mutect2, varscan2
- ADAM23 | c.1609G>T p.G537W | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52209696; called by muse, mutect2, varscan2
- ADAMTS19 | c.2854A>G p.M952V | Missense Mutation (SNP) | VAF 159/362 reads (44%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs761429937; called by muse, mutect2, varscan2
- ADAMTS5 | c.2696C>T p.T899M | Missense Mutation (SNP) | VAF 192/438 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.392); catalogued as rs368781824; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4130C>T p.P1377L | Missense Mutation (SNP) | VAF 70/394 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs780512722; called by muse, mutect2, varscan2
- ADAT3 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 218/948 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as rs1465330129, COSV100280429; called by muse, mutect2, varscan2
- ADCY9 | c.3640C>T p.R1214C | Missense Mutation (SNP) | VAF 206/405 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1278739094; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 51/584 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs757851718, COSV58443956; called by muse, mutect2
- ADD2 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 303/629 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1553374425, COSV52454724; called by muse, mutect2, varscan2
- ADGRG7 | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 185/445 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as rs747101652; called by muse, mutect2, varscan2
- ADGRL1 | c.3970G>A p.G1324R (on ENST00000340736 / NM_001008701.3; = p.G1319R on NM_014921.5) | Missense Mutation (SNP) | VAF 409/838 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0.263); catalogued as rs781735623, COSV61566889; called by muse, mutect2, varscan2
- AFF4 | c.2447C>T p.A816V | Missense Mutation (SNP) | VAF 79/430 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.685); catalogued as COSV54795056; called by muse, mutect2, varscan2
- AHCTF1 | c.3058C>T p.R1020C (on ENST00000366508; = p.R994C on NM_015446.5) | Missense Mutation (SNP) | VAF 110/246 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs914547764; called by muse, mutect2, varscan2
- AHRR | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 101/455 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs748063530, COSV57090535; called by muse, mutect2, varscan2
- AK7 | c.2065A>T p.M689L | Missense Mutation (SNP) | VAF 155/332 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV50876610; called by muse, mutect2, varscan2
- AKT1 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 130/591 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62575766; called by muse, mutect2, varscan2
- AKT2 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 249/472 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144395843, COSV60907436; called by muse, mutect2, varscan2
- ALG1L | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 178/381 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs770366017, COSV61076377; called by muse, mutect2, varscan2
- ALPK2 | c.3949G>A p.E1317K | Missense Mutation (SNP) | VAF 211/416 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs771196152, COSV64496773; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 235/589 reads (40%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- AMMECR1 | c.902del p.K301Rfs*2 | Frame Shift Del (DEL) | VAF 171/242 reads (71%) | catalogued as COSV53318934; called by mutect2, pindel, varscan2
- AMOTL2 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 379/787 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs773003068; called by muse, mutect2, varscan2
- AMOTL2 | c.599del p.P200Lfs*19 | Frame Shift Del (DEL) | VAF 64/732 reads (9%) | catalogued as rs756346527; called by mutect2, pindel
- ANK1 | c.3531T>C p.I1177= | Splice Region (SNP) | VAF 133/284 reads (47%) | catalogued as rs539159698; called by muse, mutect2, varscan2
- ANK1 | c.1282dup p.A428Gfs*43 | Frame Shift Ins (INS) | VAF 83/484 reads (17%) | catalogued as rs769735016; called by mutect2, pindel, varscan2
- ANK2 | c.10367dup p.T3457Hfs*8 | Frame Shift Ins (INS) | VAF 203/464 reads (44%) | catalogued as rs750143580; called by mutect2, varscan2
- ANKRD20A1 | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 28/29 reads (97%) | catalogued as rs1296524808; called by mutect2, varscan2
- ANKRD24 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 205/397 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs781024349, COSV99518193; called by muse, mutect2, varscan2
- ANKRD28 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 119/263 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs762410032, COSV101080763; called by muse, mutect2, varscan2
- ANKRD35 | c.94del p.D32Mfs*35 | Frame Shift Del (DEL) | VAF 243/588 reads (41%) | catalogued as rs782536263; called by mutect2, pindel, varscan2
- ANKRD36C | c.3688G>A p.V1230I | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.775); catalogued as rs966984145; called by muse, mutect2
- ANKRD36C | c.2915C>T p.P972L | Missense Mutation (SNP) | VAF 74/383 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.124); catalogued as rs765874921; called by muse, mutect2, varscan2
- ANKS1A | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 31/507 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs267600991, COSV64464286; called by muse, mutect2
- ANKUB1 | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 59/360 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101267566; called by muse, mutect2, varscan2
- ANLN | c.2429G>A p.R810H | Missense Mutation (SNP) | VAF 180/378 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs371035041, COSV56078687; called by muse, mutect2, varscan2
- ANPEP | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 200/409 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs761103812; called by muse, mutect2
- ANXA13 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 136/301 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs755136156; called by muse, mutect2, varscan2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 184/464 reads (40%) | catalogued as rs999461756; called by mutect2, pindel, varscan2
- APBA1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 369/727 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV55222939; called by muse, mutect2, varscan2
- AQP10 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 133/274 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61475916; called by muse, mutect2, varscan2
- ARAP1 | c.2177G>A p.R726Q (on ENST00000393609 / NM_001040118.2; = p.R481Q on NM_015242.4) | Missense Mutation (SNP) | VAF 172/363 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as rs376893105; called by muse, mutect2, varscan2
- ARFGAP1 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 114/404 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs138789631, COSV62262608; called by muse, mutect2
- ARGLU1 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 203/408 reads (50%) | catalogued as COSV100639788; called by muse, mutect2, varscan2
- ARHGAP22 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 388/761 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs571846097; called by muse, mutect2, varscan2
- ARHGAP28 | c.1699C>T p.R567C (on ENST00000383472 / NM_001366230.1; = p.R408C on NM_001010000.3) | Missense Mutation (SNP) | VAF 41/342 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.479); catalogued as rs751989443, COSV51634353, COSV99151102; called by muse, mutect2, varscan2
- ARHGEF12 | c.3820G>A p.V1274I | Missense Mutation (SNP) | VAF 189/436 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs747035508, COSV63103695; called by muse, mutect2, varscan2
- ARHGEF40 | c.2959C>T p.P987S | Missense Mutation (SNP) | VAF 371/826 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs775285743; called by muse, mutect2, varscan2
- ARID1A | c.4541del p.T1514Rfs*13 | Frame Shift Del (DEL) | VAF 355/822 reads (43%) | catalogued as COSV61377853; called by mutect2, pindel, varscan2
- ARID5B | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 112/261 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as rs751880754, COSV54431179; called by muse, varscan2
- ASB16 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 215/450 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV53235708; called by muse, mutect2, varscan2
- ASH1L | c.8657G>A p.R2886Q (on ENST00000368346 / NM_001366177.2; = p.R2881Q on NM_018489.3) | Missense Mutation (SNP) | VAF 236/480 reads (49%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs375668916; called by muse, mutect2, varscan2
- ASH1L | c.5051G>A p.R1684Q | Missense Mutation (SNP) | VAF 145/336 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.368); catalogued as rs1280114281, COSV100853070; called by muse, mutect2, varscan2
- ASPG | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 270/620 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV71933904; called by muse, varscan2
- ATP5MGL | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 9/246 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs1280858121; called by muse, mutect2
- ATP6V1G1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 50/508 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs1025449499, COSV100928670; called by muse, mutect2, varscan2
- ATR | c.5440del p.R1814Efs*10 | Frame Shift Del (DEL) | VAF 67/400 reads (17%) | catalogued as rs1268253442; called by mutect2, pindel, varscan2
- ATXN7L1 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 87/205 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs965075242, COSV66300128; called by muse, mutect2, varscan2
- AVPI1 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 432/881 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs573308853; called by muse, mutect2
- AXIN1 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 286/566 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200716081; called by muse, mutect2, varscan2
- AXIN2 | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 212/508 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs562176077, COSV61060141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B4GALT6 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 134/283 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1484637669, COSV52702424, COSV99380154; called by muse, mutect2, varscan2
- BAG5 | c.974del p.N325Tfs*12 | Frame Shift Del (DEL) | VAF 145/366 reads (40%) | catalogued as rs1002009532; called by mutect2, pindel, varscan2
- BCL11B | c.2500G>A p.A834T (on ENST00000357195 / NM_001282237.2; = p.A763T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 416/815 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1398057798, COSV61735370; called by muse, mutect2, varscan2
- BCL7C | c.617dup p.L207Tfs*10 | Frame Shift Ins (INS) | VAF 272/590 reads (46%) | catalogued as rs754078059; called by mutect2, varscan2
- BEND7 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 145/299 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs750048083, COSV61987087; called by muse, mutect2, varscan2
- BEST2 | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 226/508 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.771); catalogued as COSV50358847; called by muse, mutect2, varscan2
- BLMH | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 77/223 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs149410629; called by muse, mutect2, varscan2
- BMP4 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 158/418 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.55); catalogued as rs773804981, COSV55415949; called by muse, mutect2
- BOC | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 138/693 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138233485, COSV56353420; called by muse, mutect2, varscan2
- BPIFB1 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 162/352 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs1340556429; called by muse, mutect2, varscan2
- BRAF | c.2254G>A p.A752T (on ENST00000288602 / NM_001374244.1; = p.A712T on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/272 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs1481562268, COSV56110431; called by muse, varscan2
- BRD1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 314/629 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.118); catalogued as rs111730431; called by muse, mutect2, varscan2
- BRF2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 173/389 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99605064; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 101/233 reads (43%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BSPRY | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 207/397 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs771810350; called by muse, mutect2, varscan2
- C10orf88 | c.401dup p.N134Kfs*12 | Frame Shift Ins (INS) | VAF 65/150 reads (43%) | catalogued as rs751388819; called by mutect2, varscan2
- C11orf95 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 264/557 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1467117652, COSV58311346; called by muse, varscan2
- C12orf56 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 30/547 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs1225265157; called by muse, mutect2
- C19orf44 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 198/438 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs769700747, COSV55614195; called by muse, mutect2, varscan2
- C19orf84 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 230/524 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as rs765385571, COSV55740169; called by muse, mutect2, varscan2
- C1QB | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 125/493 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as rs749536477; called by muse, varscan2
- C1QTNF4 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 386/807 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56784508; called by muse, mutect2, varscan2
- C3orf20 | c.229dup p.L77Pfs*176 | Frame Shift Ins (INS) | VAF 109/572 reads (19%) | catalogued as rs1204813302; called by mutect2, pindel, varscan2
- C4B | c.3179G>A p.R1060Q | Missense Mutation (SNP) | VAF 296/402 reads (74%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.67); catalogued as rs767356444, COSV70313379; called by muse, mutect2
- C4orf47 | c.278del p.N93Ifs*2 | Frame Shift Del (DEL) | VAF 116/248 reads (47%) | catalogued as rs564059162; called by mutect2, varscan2
- C4orf54 | c.4640del p.P1547Qfs*70 | Frame Shift Del (DEL) | VAF 250/575 reads (43%) | catalogued as rs763082793; called by mutect2, pindel, varscan2
- C6 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 145/314 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs267600638, COSV54704649; called by muse, mutect2
- C6orf132 | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 213/482 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1276467013; called by muse, mutect2, varscan2
- CABIN1 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 337/668 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1389616388; called by muse, mutect2, varscan2
- CACNA1I | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 243/532 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1343508863; called by muse, mutect2, varscan2
- CADM3 | c.485G>A p.R162Q (on ENST00000368125 / NM_001127173.3; = p.R196Q on NM_021189.5) | Missense Mutation (SNP) | VAF 71/437 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs148250608; called by muse, mutect2, varscan2
- CADPS2 | c.3040del p.W1014Gfs*24 | Frame Shift Del (DEL) | VAF 170/358 reads (47%) | catalogued as rs34581969; called by mutect2, varscan2
- CALD1 | c.2234G>A p.R745H (on ENST00000361675 / NM_033138.4; = p.R490H on NM_004342.7) | Missense Mutation (SNP) | VAF 123/259 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104421090; called by muse, mutect2, varscan2
- CALN1 | c.331C>T p.R111C (on ENST00000329008 / NM_001017440.3; = p.R153C on NM_031468.4) | Missense Mutation (SNP) | VAF 138/290 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1473772101, COSV61127841, COSV61144822; called by muse, varscan2
- CAMKK1 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 187/351 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs746479390; called by muse, mutect2, varscan2
- CAPN11 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 193/403 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs372801456; called by muse, mutect2, varscan2
- CARD14 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 205/406 reads (50%) | catalogued as rs377316099; called by muse, mutect2, varscan2
- CARD9 | c.964_966del p.K322del | In Frame Del (DEL) | VAF 122/311 reads (39%) | catalogued as rs761950582; called by mutect2, pindel, varscan2
- CARD9 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 118/277 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as rs760681802; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAT | c.821A>G p.Y274C | Missense Mutation (SNP) | VAF 178/376 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV53812548; called by muse, varscan2
- CATSPER1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 237/532 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs752478488, COSV104393919; called by muse, mutect2, varscan2
- CAVIN4 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 97/204 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147081785; called by muse, mutect2, varscan2
- CCDC151 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 128/326 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs575735533; called by muse, varscan2
- CCDC183 | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 178/379 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs567294486, COSV61034614; called by muse, mutect2, varscan2
- CCDC74A | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 158/675 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.655); catalogued as rs1307989518, COSV54608973; called by muse, mutect2, varscan2
- CCDC74B | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 113/487 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as rs752589182, COSV60103550; called by muse, varscan2
- CCDC92 | c.801dup p.I268Hfs*145 | Frame Shift Ins (INS) | VAF 392/836 reads (47%) | catalogued as rs773752200; called by mutect2, varscan2
- CCIN | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 245/482 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs550023520, COSV100631738; called by muse, mutect2, varscan2
- CCND2 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 155/340 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.365); catalogued as rs373099767, COSV54223766; called by muse, mutect2, varscan2
- CCNE1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 45/580 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs189673443; called by muse, mutect2
- CCNY | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 158/350 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771715363, COSV55191875; called by muse, mutect2, varscan2
- CCT8L2 | c.344T>C p.L115S | Missense Mutation (SNP) | VAF 50/606 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372118884; called by muse, mutect2
- CD300C | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 209/447 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773477638; called by muse, mutect2, varscan2
- CD5L | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 240/475 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as rs762795478, COSV63822024; called by muse, mutect2, varscan2
- CDAN1 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 217/460 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100661187; called by muse, mutect2, varscan2
- CDCA2 | c.2860G>A p.V954I | Missense Mutation (SNP) | VAF 182/397 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs147641260; called by muse, mutect2, varscan2
- CDCA4 | c.602del p.G201Vfs*46 | Frame Shift Del (DEL) | VAF 318/746 reads (43%) | catalogued as COSV60315065; called by mutect2, pindel, varscan2
- CDH10 | c.1878T>C p.V626= | Splice Region (SNP) | VAF 87/167 reads (52%) | catalogued as COSV52596865; called by muse, mutect2, varscan2
- CDH15 | c.1537del p.H513Tfs*9 | Frame Shift Del (DEL) | VAF 349/746 reads (47%) | catalogued as rs763850576, COSV57025343; called by mutect2, varscan2
- CDH5 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 146/322 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs200378924, COSV58515664; called by muse, mutect2, varscan2
- CDH6 | c.2236G>A p.V746M | Missense Mutation (SNP) | VAF 271/553 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs538483207, COSV54064383; called by muse, mutect2, varscan2
- CDHR2 | c.1147dup p.R383Pfs*6 | Frame Shift Ins (INS) | VAF 268/673 reads (40%) | catalogued as rs774414740; called by mutect2, pindel, varscan2
- CDK20 | c.687G>A p.P229= (on ENST00000325303 / NM_001039803.3; = p.P208= on NM_012119.4) | Splice Region (SNP) | VAF 148/273 reads (54%) | catalogued as rs758770446; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4501G>A p.V1501M | Missense Mutation (SNP) | VAF 204/430 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs1384552768; called by muse, mutect2, varscan2
- CDT1 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 172/407 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766150941; called by muse, mutect2, varscan2
- CDYL2 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.749); catalogued as COSV73655097; called by muse, varscan2
- CENPC | c.406dup p.I136Nfs*4 | Frame Shift Ins (INS) | VAF 146/290 reads (50%) | catalogued as rs755030583; called by mutect2, varscan2
- CENPE | c.7515_7517del p.R2505del | In Frame Del (DEL) | VAF 58/172 reads (34%) | catalogued as rs761643711; called by pindel, varscan2
- CENPJ | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 198/401 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs758633632; called by muse, mutect2, varscan2
- CENPK | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs868259372, COSV54468361; called by muse, mutect2, varscan2
- CENPU | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 132/294 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs762461896; called by muse, mutect2, varscan2
- CEP104 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 28/459 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778307777; called by muse, mutect2
- CEP85 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs183440117; called by muse, mutect2, varscan2
- CHD3 | c.3514C>T p.R1172W | Missense Mutation (SNP) | VAF 160/308 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867862540; called by muse, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 96/184 reads (52%) | catalogued as rs1322050057; called by mutect2, varscan2
- CHRM1 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 279/578 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.075); catalogued as rs541812336; called by muse, mutect2, varscan2
- CLDN17 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 200/523 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.164); catalogued as COSV54523564; called by muse, mutect2, varscan2
- CLIP4 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773730812; called by muse, mutect2, varscan2
- CLK2 | c.301T>C p.Y101H | Missense Mutation (SNP) | VAF 389/747 reads (52%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.69); catalogued as rs1361010427; called by muse, mutect2, varscan2
- CLPTM1L | c.1408A>G p.T470A | Missense Mutation (SNP) | VAF 99/583 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as rs1355591171; called by muse, mutect2, varscan2
- CLYBL | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 74/704 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); catalogued as rs749597182; called by muse, varscan2
- CNGA4 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 214/488 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as rs182305554; called by muse, varscan2
- CNGB3 | c.1266del p.Q423Nfs*3 | Frame Shift Del (DEL) | VAF 165/427 reads (39%) | catalogued as COSV100181075; called by mutect2, pindel, varscan2
- CNTN5 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 109/234 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.823); catalogued as rs577962852, COSV54312220; called by muse, mutect2, varscan2
- CNTNAP5 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 121/252 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs890816163, COSV70496411, COSV70507161; called by muse, mutect2, varscan2
- COBL | c.3484G>A p.G1162S | Missense Mutation (SNP) | VAF 261/520 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1471847831; called by muse, mutect2, varscan2
- COBLL1 | c.2608C>T p.P870S (on ENST00000392717; = p.P832S on NM_014900.5) | Missense Mutation (SNP) | VAF 88/385 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as COSV52065454; called by muse, mutect2, varscan2
- COIL | c.192del p.L65Sfs*11 | Frame Shift Del (DEL) | VAF 189/434 reads (44%) | catalogued as rs763239843; called by mutect2, pindel, varscan2
- COL18A1 | c.1435G>A p.V479I (on ENST00000359759 / NM_130444.3; = p.V244I on NM_030582.4) | Missense Mutation (SNP) | VAF 438/984 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs532978021, COSV62702400; called by muse, mutect2, varscan2
- COL19A1 | c.3361G>T p.G1121* | Nonsense Mutation (SNP) | VAF 156/311 reads (50%) | catalogued as COSV59576433; called by muse, mutect2, varscan2
- COL3A1 | c.1585G>A p.V529I | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs140257722, COSV100483795; ClinVar: uncertain significance; called by muse, varscan2
- COL4A5 | c.3938G>A p.R1313Q | Missense Mutation (SNP) | VAF 120/120 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs776661566, COSV100087309, COSV60360107; called by muse, mutect2, varscan2
- COL5A1 | c.4157C>T p.S1386L | Missense Mutation (SNP) | VAF 163/400 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs141605663; called by muse, varscan2
- COL5A2 | c.3353G>A p.R1118H | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771543878; called by muse, varscan2
- COL6A1 | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 65/693 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100720174; called by muse, mutect2
- COLEC11 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 36/670 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs759032478; called by muse, mutect2
- COLGALT2 | c.595T>C p.Y199H | Missense Mutation (SNP) | VAF 60/347 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62730545; called by muse, mutect2, varscan2
- COQ8A | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 322/656 reads (49%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs751042244; called by muse, varscan2
- CORO7-PAM16 | c.3143C>T p.T1048M | Missense Mutation (SNP) | VAF 224/475 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as rs148571756; called by muse, mutect2, varscan2
- CPAMD8 | c.4565C>T p.T1522M (on ENST00000651564; = p.T1475M on NM_015692.5) | Missense Mutation (SNP) | VAF 197/389 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs746583525, COSV71596398; called by muse, mutect2, varscan2
- CRIP2 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 300/701 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1555436514; called by muse, mutect2, varscan2
- CRTAC1 | c.1805G>A p.G602D | Missense Mutation (SNP) | VAF 167/365 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (1); catalogued as rs1326553035; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 150/322 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781765380, COSV65675428; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 41/251 reads (16%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSNKA2IP | c.1637C>A p.P546H | Missense Mutation (SNP) | VAF 180/319 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.972); catalogued as rs1001045965; called by muse, mutect2, varscan2
- CSPG4 | c.3851C>T p.A1284V | Missense Mutation (SNP) | VAF 259/514 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.118); catalogued as rs1463586155; called by muse, mutect2, varscan2
- CTAGE1 | c.2201del p.P734Qfs*22 | Frame Shift Del (DEL) | VAF 201/421 reads (48%) | catalogued as COSV101194644; called by mutect2, pindel, varscan2
- CTDP1 | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 350/772 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752099626; called by muse, mutect2, varscan2
- CTIF | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 228/503 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.038); catalogued as rs1227058755; called by muse, mutect2, varscan2
- CXCR3 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 339/340 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1415409982; called by muse, mutect2, varscan2
- CYP11B1 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 294/611 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149881706, CM144426; ClinVar: not provided; called by muse, mutect2, varscan2
- CYP1A1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 252/546 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as rs368952331; called by muse, varscan2
- CYP3A5 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs781386975, COSV56121009, COSV56122738; called by muse, mutect2, varscan2
- DAAM1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 159/393 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1566703084; called by muse, varscan2
- DCST1 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 200/396 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs779301834; called by muse, mutect2, varscan2
- DCTN1 | c.3127C>T p.R1043C | Missense Mutation (SNP) | VAF 252/558 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs140066692; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCTN1 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 292/585 reads (50%) | catalogued as rs866457869, COSV62619563; called by muse, mutect2, varscan2
- DDHD2 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 34/556 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763476356, COSV68157058; called by muse, mutect2
- DDR1 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 277/585 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs112048001; called by muse, mutect2, varscan2
- DDX43 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 144/335 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs541292561, COSV64836881; called by muse, varscan2
- DDX60L | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 161/374 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776813390, COSV99487479, COSV99487904; called by muse, mutect2, varscan2
- DENND2B | c.2584C>T p.R862W | Missense Mutation (SNP) | VAF 183/380 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1436982519, COSV100567389; called by muse, mutect2, varscan2
- DENND4B | c.3302G>A p.R1101Q | Missense Mutation (SNP) | VAF 59/730 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs781435616, COSV63409850; called by muse, mutect2
- DERPC | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 182/400 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.83); catalogued as rs200740384; called by muse, mutect2, varscan2
- DHX37 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 262/516 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs369885446, COSV58131585; called by muse, mutect2, varscan2
- DHX38 | c.3551G>A p.R1184Q | Missense Mutation (SNP) | VAF 173/405 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1286240734, COSV51696323; called by muse, mutect2, varscan2
- DIAPH3 | c.958del p.I320Lfs*20 (on ENST00000400324 / NM_001042517.2; = p.I57Lfs*20 on NM_030932.3) | Frame Shift Del (DEL) | VAF 125/252 reads (50%) | catalogued as rs755069320; called by mutect2, varscan2
- DIPK1A | c.765_767del p.R255del | In Frame Del (DEL) | VAF 147/328 reads (45%) | catalogued as rs751906373; called by pindel, varscan2
- DIPK1B | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 247/535 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.286); catalogued as rs751619988; called by muse, mutect2, varscan2
- DISP2 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 65/375 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143054067, COSV99140581; called by muse, mutect2, varscan2
- DLC1 | c.3989A>G p.D1330G (on ENST00000276297 / NM_001348081.2; = p.D893G on NM_006094.5) | Missense Mutation (SNP) | VAF 163/376 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs758920737; called by muse, mutect2, varscan2
- DLGAP4 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 90/1218 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs367982678; called by muse, mutect2
- DMBT1 | c.7400G>A p.R2467H (on ENST00000338354 / NM_001377530.1; = p.R1710H on NM_004406.3) | Missense Mutation (SNP) | VAF 69/458 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs373485754; called by muse, mutect2
- DMXL2 | c.1871G>A p.W624* | Nonsense Mutation (SNP) | VAF 146/350 reads (42%) | catalogued as COSV99196592; called by muse, mutect2, varscan2
- DNAAF5 | c.2032G>A p.V678M | Missense Mutation (SNP) | VAF 158/716 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as rs779461495, COSV52416368; called by muse, mutect2, varscan2
- DNAH10 | c.5962C>T p.R1988C (on ENST00000409039; = p.R1927C on NM_207437.3) | Missense Mutation (SNP) | VAF 257/575 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs748691740; called by muse, mutect2, varscan2
- DNAH11 | c.13345C>T p.R4449C | Missense Mutation (SNP) | VAF 153/342 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs751222708, CM157452, COSV100181521; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH2 | c.10414G>A p.D3472N | Missense Mutation (SNP) | VAF 71/379 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs139792492; called by muse, mutect2, varscan2
- DNAH3 | c.8168C>T p.A2723V | Missense Mutation (SNP) | VAF 99/524 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.129); catalogued as rs148454192, COSV54516556, COSV54531302; called by muse, mutect2, varscan2
- DNASE1 | c.552C>T p.D184= | Splice Region (SNP) | VAF 24/390 reads (6%) | catalogued as rs769436738, COSV55912909; called by muse, mutect2
- DOCK5 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 229/456 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs369802050; called by muse, mutect2, varscan2
- DOCK7 | c.5183G>T p.R1728L (on ENST00000635253 / NM_001367561.1; = p.R1697L on NM_033407.3) | Missense Mutation (SNP) | VAF 149/328 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.115); catalogued as COSV99226095; called by muse, mutect2, varscan2
- DOK1 | c.35dup p.L12Ffs*33 | Frame Shift Ins (INS) | VAF 193/474 reads (41%) | catalogued as rs759252474; called by mutect2, varscan2
- DOT1L | c.4184C>T p.P1395L | Missense Mutation (SNP) | VAF 423/909 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as rs750419812; called by muse, mutect2, varscan2
- DPP6 | c.2077C>T p.R693W (on ENST00000377770 / NM_001364500.2; = p.R631W on NM_001936.5) | Missense Mutation (SNP) | VAF 236/454 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs869025385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DRD5 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 203/400 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs775864675, COSV58576954; called by muse, mutect2, varscan2
- DSP | c.5794C>T p.R1932C | Missense Mutation (SNP) | VAF 193/436 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs748825632, COSV65790689; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2H1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 63/339 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs769288132, COSV62095337; called by muse, mutect2, varscan2
- DYNC2H1 | c.6649C>T p.R2217* | Nonsense Mutation (SNP) | VAF 96/209 reads (46%) | catalogued as rs756087785, COSV100518515; called by muse, mutect2, varscan2
- DYRK1B | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 121/594 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.982); catalogued as rs563920364; called by muse, mutect2, varscan2
- DZIP1L | c.1459C>A p.L487M | Missense Mutation (SNP) | VAF 186/428 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs889086878; called by muse, mutect2, varscan2
- E2F3 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 381/776 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60896100; called by mutect2, varscan2
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 72/180 reads (40%) | catalogued as rs746509911; called by mutect2, varscan2
- ECH1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 35/663 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs764029520, COSV55490066; called by muse, mutect2
- ECHDC2 | c.583C>T p.R195* (on ENST00000371522 / NM_001198961.2; = p.R164* on NM_018281.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 280/605 reads (46%) | catalogued as rs376450584; called by muse, mutect2, varscan2
- ECM1 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 298/579 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs768430337, COSV60871537, COSV60873197; called by muse, varscan2
- ECM2 | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151070730; called by muse, mutect2
- EDEM1 | c.92T>G p.M31R | Missense Mutation (SNP) | VAF 367/772 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as rs761254037; called by muse, mutect2, varscan2
- EFCAB5 | c.450del p.K150Nfs*17 | Frame Shift Del (DEL) | VAF 171/372 reads (46%) | catalogued as rs760813779; called by mutect2, varscan2
- EFCAB5 | c.2606G>A p.R869Q | Missense Mutation (SNP) | VAF 131/281 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.829); catalogued as rs894068935, COSV57926065; called by muse, mutect2, varscan2
- EHD2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 181/450 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs745870470, COSV54409849; called by muse, mutect2, varscan2
- EIF3A | c.2575C>T p.R859C | Missense Mutation (SNP) | VAF 251/527 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs374609913; called by muse, mutect2, varscan2
- EIF4G1 | c.3469C>T p.R1157* (on ENST00000346169 / NM_198241.3; = p.R962* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 244/476 reads (51%) | catalogued as COSV100071916; called by muse, varscan2
- EIF4G3 | c.2454G>A p.T818= | Splice Region (SNP) | VAF 149/286 reads (52%) | catalogued as COSV51679669, COSV51695427; called by muse, mutect2, varscan2
- EIF5 | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 127/299 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs756212895; called by muse, mutect2, varscan2
- EMC1 | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs755215386; called by muse, mutect2, varscan2
- EML6 | c.3095G>A p.R1032H | Missense Mutation (SNP) | VAF 158/352 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.72); catalogued as rs761285924; called by muse, mutect2, varscan2
- EP400 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 241/534 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as rs769410643; called by muse, mutect2, varscan2
- EPB41L1 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 172/346 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs200279989; called by muse, mutect2, varscan2
- EPB41L5 | c.802del p.W268Gfs*4 | Frame Shift Del (DEL) | VAF 74/212 reads (35%) | catalogued as rs35675992; called by mutect2, pindel, varscan2
- EPHB1 | c.2593C>T p.R865W | Missense Mutation (SNP) | VAF 268/552 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758204492, COSV67653431; called by muse, mutect2, varscan2
- EPHB3 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 228/458 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs200203653; called by muse, mutect2, varscan2
- EPPK1 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 166/722 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as rs782642241, COSV73261737; called by muse, mutect2, varscan2
- ERCC6 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 233/495 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs376040533; called by muse, mutect2, varscan2
- ERG28 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 119/296 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs751084984, COSV53162238; called by muse, mutect2, varscan2
- ERN2 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 200/431 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99891145; called by muse, mutect2, varscan2
- ETS2 | c.1327G>A p.V443M | Missense Mutation (SNP) | VAF 279/622 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs558667507; called by muse, mutect2, varscan2
- EXOSC1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 36/293 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs903760300, COSV58355560; called by muse, mutect2, varscan2
- EYS | c.1961dup p.N654Kfs*5 | Frame Shift Ins (INS) | VAF 152/379 reads (40%) | catalogued as rs749103801; called by mutect2, pindel, varscan2
- EYS | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 108/490 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as rs528733427, CM121447, COSV100676849, COSV60982705, COSV60993480; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM110B | c.548G>A p.R183K | Missense Mutation (SNP) | VAF 33/641 reads (5%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.931); catalogued as COSV64066833; called by muse, mutect2
- FAM117B | c.1144dup p.L382Pfs*6 | Frame Shift Ins (INS) | VAF 175/340 reads (51%) | catalogued as rs761783143; called by mutect2, varscan2
- FAM160B2 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 298/616 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.103); catalogued as rs747782138, COSV57161689; called by muse, mutect2, varscan2
- FAM184B | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 166/372 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs1226238277; called by muse, mutect2, varscan2
- FAM205C | c.71T>C p.I24T | Missense Mutation (SNP) | VAF 228/428 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs935816750; called by muse, mutect2, varscan2
- FAM216B | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 104/221 reads (47%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs749283387, COSV58270230; called by muse, mutect2, varscan2
- FAM234B | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 139/297 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs373610349; called by muse, mutect2, varscan2
- FAM71E2 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 193/391 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1023517181; called by muse, mutect2, varscan2
- FAM81B | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 201/414 reads (49%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as COSV51985937; called by muse, mutect2, varscan2
- FARSA | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 167/323 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs761259713; called by muse, mutect2, varscan2
- FAT3 | c.9386del p.P3129Lfs*22 | Frame Shift Del (DEL) | VAF 164/354 reads (46%) | catalogued as COSV99962642; called by mutect2, varscan2
- FAT3 | c.11077G>A p.V3693M | Missense Mutation (SNP) | VAF 244/444 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1036470545; called by muse, mutect2, varscan2
- FBN2 | c.3061C>T p.R1021C | Missense Mutation (SNP) | VAF 202/445 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541842635, CM148688, COSV52521856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL18 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 329/633 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.606); catalogued as rs868062527; called by muse, mutect2, varscan2
- FBXO10 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 124/265 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52833761; called by muse, mutect2, varscan2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 68/256 reads (27%) | catalogued as rs772635228; called by mutect2, varscan2
- FCHSD1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 195/473 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1287682299; called by muse, mutect2, varscan2
- FCN3 | c.383dup p.G129Rfs*32 | Frame Shift Ins (INS) | VAF 182/434 reads (42%) | catalogued as rs750716179; called by mutect2, pindel, varscan2
- FGD6 | c.3302G>A p.R1101Q | Missense Mutation (SNP) | VAF 53/409 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1416061781, COSV59690240; called by muse, mutect2, varscan2
- FGF7 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 172/367 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1163604663, COSV51066093; called by muse, mutect2, varscan2
- FHOD3 | c.3922G>A p.A1308T (on ENST00000359247 / NM_001281739.3; = p.A1325T on NM_025135.5) | Missense Mutation (SNP) | VAF 112/590 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV57185320; called by muse, mutect2, varscan2
- FLNA | c.7585G>A p.E2529K (on ENST00000369850 / NM_001110556.2; = p.E2521K on NM_001456.3) | Missense Mutation (SNP) | VAF 56/335 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1557175308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNB | c.6490G>A p.V2164M | Missense Mutation (SNP) | VAF 349/670 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as rs770824421, COSV99914626; called by muse, mutect2, varscan2
- FLRT2 | c.1954G>A p.V652M | Missense Mutation (SNP) | VAF 214/407 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58145198; called by muse, mutect2, varscan2
- FLT1 | c.1514T>C p.I505T | Missense Mutation (SNP) | VAF 69/358 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs751112254, COSV56730448; called by muse, varscan2
- FLT4 | c.89dup p.T31Dfs*15 | Frame Shift Ins (INS) | VAF 234/466 reads (50%) | catalogued as rs755445139; called by mutect2, varscan2
- FLVCR1 | c.154del p.A52Pfs*61 | Frame Shift Del (DEL) | VAF 142/741 reads (19%) | catalogued as rs747017639; called by mutect2, varscan2
- FN3KRP | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 206/455 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372059941; called by muse, mutect2, varscan2
- FOXR1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 223/497 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs782072466; called by muse, mutect2, varscan2
- FREM2 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 213/453 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs367642497; called by muse, mutect2, varscan2
- FRMD1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 120/539 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765036020, COSV99349550; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 16/156 reads (10%) | catalogued as rs1348158626; called by mutect2, varscan2
- FURIN | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 190/435 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752966657, COSV51574592; called by muse, mutect2, varscan2
- FZD8 | c.2030C>T p.S677L | Missense Mutation (SNP) | VAF 139/293 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.173); catalogued as rs1483871697; called by muse, mutect2, varscan2
- GABPB2 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 131/289 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.207); catalogued as COSV64461135; called by muse, mutect2, varscan2
- GABRA5 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 262/517 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV100164945, COSV59482802; called by muse, mutect2, varscan2
- GABRG2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 112/213 reads (53%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.649); catalogued as rs772800839, COSV62716849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATA3 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 335/672 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs766641914, CX160948; called by muse, mutect2, varscan2
- GBP4 | c.1556T>C p.L519P | Missense Mutation (SNP) | VAF 47/335 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs776395231; called by muse, mutect2
- GCGR | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 184/381 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs527317042, COSV99076881; called by muse, mutect2, varscan2
- GDAP1L1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 250/493 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1000998948; called by muse, mutect2, varscan2
- GGA2 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 157/345 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754373988; called by muse, mutect2, varscan2
- GGN | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 383/771 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1474770509, COSV53057252; called by muse, mutect2, varscan2
- GGNBP2 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as rs963224918; called by muse, mutect2
- GGT5 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 202/404 reads (50%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as rs748665403; called by muse, mutect2, varscan2
- GGT7 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 146/312 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs756441036, COSV60540325; called by muse, mutect2, varscan2
- GK5 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 14/324 reads (4%) | catalogued as COSV67485691; called by muse, mutect2
- GLIS1 | c.1060C>A p.R354S | Missense Mutation (SNP) | VAF 189/374 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs59283679, COSV56547072; called by muse, mutect2, varscan2
- GLYCTK | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 286/656 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs772552756; called by muse, mutect2, varscan2
- GMPS | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 166/380 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs371983046; called by muse, mutect2, varscan2
- GNA11 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 84/488 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769503200, COSV50027047; called by muse, varscan2
- GNB1L | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 306/642 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV61548607; called by muse, mutect2, varscan2
- GNGT2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 142/342 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV55930094; called by muse, mutect2, varscan2
- GOLGA6L9 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 86/693 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.402); catalogued as rs1255983625; called by mutect2, varscan2
- GPN1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs776562382; called by muse, mutect2, varscan2
- GPR149 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 176/374 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs191694043; called by muse, mutect2, varscan2
- GRIA2 | c.2623G>A p.V875I | Missense Mutation (SNP) | VAF 118/254 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.959); catalogued as COSV52387006; called by muse, mutect2, varscan2
- GRIK5 | c.1189C>A p.L397M | Missense Mutation (SNP) | VAF 25/541 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99491506; called by muse, mutect2
- GRK2 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 38/522 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1455500216; called by muse, mutect2
- GRM2 | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 272/541 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754332134, COSV56585189; called by muse, mutect2, varscan2
- GRM7 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 158/374 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs370675167; called by muse, varscan2
- GTF2F1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 214/439 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201459418; called by muse, mutect2, varscan2
- GUCA1B | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 196/434 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.595); catalogued as rs1187293594; called by muse, mutect2, varscan2
- GUK1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 309/644 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs776681463, COSV57157219; called by muse, mutect2, varscan2
- H3C6 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 143/303 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs770438126, COSV64519480; called by muse, mutect2, varscan2
- HCCS | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58239551; called by muse, mutect2, varscan2
- HCN1 | c.1676G>A p.C559Y | Missense Mutation (SNP) | VAF 158/352 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57528817; called by muse, mutect2, varscan2
- HCN3 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 353/700 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs781074367; called by muse, mutect2, varscan2
- HECTD4 | c.13100dup p.D4368Rfs*44 | Frame Shift Ins (INS) | VAF 74/324 reads (23%) | catalogued as rs746492036; called by mutect2, varscan2
- HECTD4 | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1431352056; called by muse, mutect2, varscan2
- HHATL | c.1330C>A p.L444I | Missense Mutation (SNP) | VAF 217/470 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV55132602; called by muse, mutect2, varscan2
- HIF1A | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 37/501 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs199775054, COSV60190973; called by muse, mutect2
- HIPK4 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 200/442 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs1057246320; called by muse, mutect2, varscan2
- HK1 | c.2728C>T p.R910W | Missense Mutation (SNP) | VAF 261/505 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867948527; called by muse, varscan2
- HKDC1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 155/392 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs149059487; called by muse, mutect2, varscan2
- HMCN1 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 18/309 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs531770127, COSV54903513; called by muse, mutect2
- HMG20B | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 348/739 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs755433105, COSV99503155; called by muse, mutect2, varscan2
- HMGCR | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 147/299 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs139887868; called by muse, mutect2, varscan2
- HNRNPM | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 102/260 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV57692103; called by muse, mutect2, varscan2
- HPCAL1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 68/404 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV57147810; called by muse, mutect2, varscan2
- HPS5 | c.2042del p.K681Rfs*4 (on ENST00000349215 / NM_181507.2; = p.K567Rfs*4 on NM_007216.4) | Frame Shift Del (DEL) | VAF 51/284 reads (18%) | catalogued as rs1564940513; called by mutect2, pindel, varscan2
- HS3ST1 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 244/469 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1161685509, COSV50023426; called by muse, varscan2
- HS6ST3 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 210/428 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs778172720, COSV65012226; called by muse, varscan2
- HSPA5 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 85/521 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.774); catalogued as rs753498680; called by muse, mutect2, varscan2
- HSPD1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 174/336 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs768557320, COSV61443619, COSV61444464; called by muse, mutect2, varscan2
- HSPG2 | c.9421C>T p.R3141C | Missense Mutation (SNP) | VAF 322/718 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs560125766; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HYAL4 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs766347554, COSV56138716; called by muse, mutect2
- IFIH1 | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 140/286 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1427762000; called by muse, mutect2, varscan2
- IFT140 | c.3671C>T p.A1224V | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs369161842; called by muse, mutect2, varscan2
- IFT172 | c.3052C>T p.R1018C | Missense Mutation (SNP) | VAF 221/476 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs1358114348, COSV53132749, COSV53140988; called by muse, mutect2, varscan2
- IGLV3-27 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 136/345 reads (39%) | catalogued as rs751481735; called by mutect2, pindel, varscan2
- IL17RA | c.2177C>T p.S726L | Missense Mutation (SNP) | VAF 368/748 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as rs756332306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL1RN | c.419C>T p.A140V (on ENST00000409930 / NM_173842.3; = p.A122V on NM_000577.5) | Missense Mutation (SNP) | VAF 146/582 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1467369472; called by muse, mutect2, varscan2
- IL27 | c.31+1G>A p.X11_splice | Splice Site (SNP) | VAF 299/618 reads (48%) | catalogued as COSV63559654; called by muse, mutect2, varscan2
- IL4R | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 300/635 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.333); catalogued as rs1567340037, COSV50146733; called by muse, mutect2, varscan2
- INAVA | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 312/626 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.765); catalogued as rs374236435; called by muse, mutect2, varscan2
- INCENP | c.2048G>A p.R683Q (on ENST00000394818 / NM_001040694.2; = p.R679Q on NM_020238.3) | Missense Mutation (SNP) | VAF 511/1001 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs780288058; called by muse, mutect2, varscan2
- INO80D | c.1772C>T p.T591M | Missense Mutation (SNP) | VAF 132/320 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768036031, COSV68958950; called by muse, mutect2, varscan2
- INPP5J | c.1788C>T p.D596= (on ENST00000331075 / NM_001284285.2; = p.D228= on NM_001002837.2) | Splice Region (SNP) | VAF 116/241 reads (48%) | catalogued as rs751122202; called by muse, mutect2, varscan2
- IPO4 | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 171/405 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs559669192, COSV61016301; called by muse, mutect2, varscan2
- IQCE | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 168/406 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs976202890; called by muse, mutect2, varscan2
- IRF4 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 25/554 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.091); catalogued as rs1472591082; called by muse, mutect2
- ITGA1 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 133/312 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.695); catalogued as rs533895653; called by muse, mutect2, varscan2
- ITGAX | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 264/549 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.308); catalogued as rs1312125550; called by muse, mutect2, varscan2
- ITGB8 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.051); catalogued as rs376359729; called by muse, mutect2, varscan2
- ITPR3 | c.7570C>T p.R2524C | Missense Mutation (SNP) | VAF 196/400 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65267690; called by muse, mutect2, varscan2
- JAKMIP2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 215/408 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1362243851, COSV54603261; called by muse, mutect2, varscan2
- JCAD | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 102/460 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs758635835, COSV64758777; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1783A>G p.T595A | Missense Mutation (SNP) | VAF 44/682 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1453524342; called by muse, mutect2
- KANK4 | c.1390G>T p.G464W | Missense Mutation (SNP) | VAF 236/438 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV62987892; called by muse, varscan2
- KATNB1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 62/776 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as rs782790122; called by muse, mutect2
- KBTBD13 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 381/790 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as rs1442072492; called by muse, mutect2, varscan2
- KCNA1 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 258/557 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778463081, COSV66836531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNAB1 | c.439G>A p.A147T (on ENST00000490337 / NM_172160.3; = p.A136T on NM_003471.3) | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1288399948; called by muse, mutect2, varscan2
- KCND2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 46/596 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV58600030; called by muse, mutect2
- KCNG2 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 364/798 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as rs1280106577, COSV60267436; called by muse, mutect2, varscan2
- KCNG2 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 484/950 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs559125277, COSV60267628; called by muse, mutect2, varscan2
- KCNH1 | c.2708G>A p.R903Q (on ENST00000271751 / NM_172362.3; = p.R876Q on NM_002238.4) | Missense Mutation (SNP) | VAF 276/552 reads (50%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs367722512; called by muse, mutect2, varscan2
- KCNH6 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 195/500 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.153); catalogued as rs745912077, COSV100120894; called by muse, mutect2, varscan2
- KCNH7 | c.2245dup p.A749Gfs*3 | Frame Shift Ins (INS) | VAF 205/538 reads (38%) | catalogued as rs757276514; called by mutect2, pindel, varscan2
- KCNN2 | c.156_158dup p.A58dup (on ENST00000264773; = p.A270dup on NM_021614.4) | In Frame Ins (INS) | VAF 46/378 reads (12%) | catalogued as rs1347338421; called by mutect2, pindel
- KCP | c.2522A>G p.Q841R (on ENST00000620378; = p.Q901R on NM_001366122.1) | Missense Mutation (SNP) | VAF 87/383 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1232476535; called by muse, mutect2, varscan2
- KIAA1217 | c.5639C>T p.P1880L | Missense Mutation (SNP) | VAF 242/530 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371035355; called by muse, mutect2, varscan2
- KIAA1549 | c.848del p.L283* | Frame Shift Del (DEL) | VAF 88/417 reads (21%) | catalogued as rs752375544, COSV54318481; called by mutect2, varscan2
- KIAA2012 | c.2536del p.T846Qfs*16 | Frame Shift Del (DEL) | VAF 208/426 reads (49%) | catalogued as rs753894409; called by mutect2, varscan2
- KIAA2026 | c.5561C>T p.S1854L | Missense Mutation (SNP) | VAF 78/368 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs747361371; called by muse, mutect2, varscan2
- KIDINS220 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 166/386 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as rs377048648; called by muse, varscan2
- KIF13A | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 35/513 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99435206; called by muse, mutect2
- KIF15 | c.911A>T p.D304V | Missense Mutation (SNP) | VAF 81/372 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773384115; called by muse, mutect2, varscan2
- KIF20A | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 201/459 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV50165966; called by muse, mutect2, varscan2
- KIF20B | c.5332C>T p.R1778W (on ENST00000371728 / NM_001284259.2; = p.R1738W on NM_016195.4) | Missense Mutation (SNP) | VAF 26/480 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs1009246322; called by muse, mutect2
- KIF26B | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 479/962 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs201344288; called by muse, mutect2, varscan2
- KIF26B | c.6004C>T p.R2002W | Missense Mutation (SNP) | VAF 46/430 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs201961374; called by muse, mutect2, varscan2
- KIF27 | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 175/350 reads (50%) | SIFT tolerated (0.81); PolyPhen benign (0.122); catalogued as rs996995862; called by muse, mutect2, varscan2
- KIF7 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 85/902 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs967375546; called by muse, mutect2
- KIFC1 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 334/666 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as rs763949680, COSV65728481; called by muse, varscan2
- KMT2B | c.4235del p.G1412Afs*10 | Frame Shift Del (DEL) | VAF 371/942 reads (39%) | catalogued as rs34078597; called by mutect2, pindel, varscan2
- KMT2B | c.7828C>T p.R2610C | Missense Mutation (SNP) | VAF 231/473 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs866415691, COSV53076704; called by muse, mutect2, varscan2
- KMT2C | c.12484C>T p.R4162W | Missense Mutation (SNP) | VAF 186/393 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as rs201883770; called by muse, mutect2, varscan2
- KNOP1 | c.391del p.T131Pfs*82 | Frame Shift Del (DEL) | VAF 112/541 reads (21%) | catalogued as rs780571889; called by mutect2, pindel, varscan2
- KRTAP10-1 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 240/615 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as rs377199619; called by muse, mutect2, varscan2
- KRTAP2-4 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 190/810 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1445319135; called by muse, mutect2, varscan2
- KSR1 | c.2225G>A p.R742Q (on ENST00000644974 / NM_001367810.1; = p.R627Q on NM_014238.2) | Missense Mutation (SNP) | VAF 156/303 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52037817; called by muse, mutect2, varscan2
- KY | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 155/331 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772213051, COSV71017887; called by muse, mutect2, varscan2
- L3MBTL2 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 285/554 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs1411607374, COSV53432784; called by muse, mutect2, varscan2
- LCK | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 173/407 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV60738916; called by muse, mutect2, varscan2
- LDHD | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 260/595 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as rs768958694; called by muse, mutect2, varscan2
- LECT2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 172/376 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752821818, COSV50847172; called by muse, mutect2, varscan2
- LIMA1 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 128/277 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs1565824241; called by muse, mutect2, varscan2
- LLGL1 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 357/721 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs557754934; called by muse, mutect2, varscan2
- LMNA | c.1862C>T p.T621M | Missense Mutation (SNP) | VAF 316/688 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as rs765594825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMNTD1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 35/419 reads (8%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as rs1013869500; called by muse, mutect2
- LMTK3 | c.3244G>A p.G1082R | Missense Mutation (SNP) | VAF 189/857 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1003487730; called by muse, mutect2, varscan2
- LRP1 | c.8356G>A p.V2786M | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as rs767661661; called by muse, mutect2, varscan2
- LRP2BP | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 90/225 reads (40%) | catalogued as rs143178247; called by muse, mutect2, varscan2
- LRRC14B | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 54/664 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs780974739; called by muse, mutect2
- LRRC36 | c.487A>G p.S163G | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV52082760; called by muse, mutect2, varscan2
- LRRC3B | c.601del p.T201Lfs*17 | Frame Shift Del (DEL) | VAF 177/443 reads (40%) | catalogued as COSV67521526; called by mutect2, pindel, varscan2
- LRRC43 | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 80/389 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60289801; called by muse, mutect2, varscan2
- LRRC4B | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 397/837 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.623); catalogued as rs376100575; called by muse, mutect2, varscan2
- LRRC63 | c.1355del p.F452Sfs*6 | Frame Shift Del (DEL) | VAF 137/325 reads (42%) | catalogued as rs778311228; called by mutect2, pindel, varscan2
- LRRTM1 | c.762G>T p.W254C | Missense Mutation (SNP) | VAF 112/540 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54439538; called by muse, mutect2, varscan2
- LSM14B | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 158/713 reads (22%) | catalogued as COSV53378891; called by muse, mutect2, varscan2
- LTBP3 | c.3679C>T p.R1227C (on ENST00000301873 / NM_001130144.3; = p.R1180C on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 344/654 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1397716583; called by muse, mutect2, varscan2
- LUC7L | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 266/541 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs766717488, COSV53459056; called by muse, mutect2, varscan2
- LUC7L2 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 154/369 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs370412964; called by muse, mutect2, varscan2
- LUC7L2 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 183/366 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs763185073, COSV54923949; called by muse, mutect2, varscan2
- MAB21L4 | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 286/624 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs867189724; called by muse, varscan2
- MAD1L1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 153/695 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs971692328; called by muse, mutect2, varscan2
- MAFK | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 306/616 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780987418; called by muse, mutect2, varscan2
- MAP2K7 | c.875dup p.D293Rfs*8 | Frame Shift Ins (INS) | VAF 74/385 reads (19%) | catalogued as rs1340827824; called by mutect2, pindel, varscan2
- MAP3K10 | c.2749G>T p.D917Y | Missense Mutation (SNP) | VAF 326/715 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs1408633369; called by muse, mutect2, varscan2
- MAP4K4 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 120/243 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.739); catalogued as rs1352923057; called by muse, mutect2, varscan2
- MAP7 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 233/508 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361780560, COSV63422952; called by muse, mutect2, varscan2
- MAPK13 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 232/453 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV52982816; called by muse, mutect2, varscan2
- MARCHF7 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 200/413 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52028824; called by muse, mutect2, varscan2
- MAST1 | c.3790G>A p.V1264M | Missense Mutation (SNP) | VAF 141/750 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs886143941; called by muse, mutect2, varscan2
- MBTPS1 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 195/417 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as rs1350687564; called by muse, mutect2, varscan2
- MCM10 | c.2155del p.R719Gfs*17 (on ENST00000484800 / NM_182751.3; = p.R718Gfs*17 on NM_018518.5) | Frame Shift Del (DEL) | VAF 32/383 reads (8%) | catalogued as rs1310004144; called by mutect2, pindel
- MCM7 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 264/571 reads (46%) | catalogued as rs561439468, COSV57999776; called by muse, mutect2, varscan2
- MCOLN1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 288/598 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as rs199685178, COSV51176270; called by muse, mutect2, varscan2
- MEIS2 | c.784C>T p.P262S (on ENST00000561208 / NM_170675.5; = p.P249S on NM_002399.3) | Missense Mutation (SNP) | VAF 143/347 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as rs780669823; called by muse, mutect2, varscan2
- MFN2 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs958009351; called by muse, mutect2, varscan2
- MIA2 | c.1089del p.D364Tfs*8 | Frame Shift Del (DEL) | VAF 40/244 reads (16%) | catalogued as rs538500709; called by mutect2, varscan2
- MIA2 | c.2309T>C p.F770S | Missense Mutation (SNP) | VAF 122/346 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs777151026, COSV54492262, COSV54496612; called by mutect2, varscan2
- MICAL1 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 130/283 reads (46%) | catalogued as rs201978922, COSV57807061; called by muse, mutect2, varscan2
- MICOS13 | c.150dup p.A51Rfs*32 | Frame Shift Ins (INS) | VAF 120/577 reads (21%) | catalogued as rs751944867; called by mutect2, varscan2
- MN1 | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 404/876 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV56558353; called by muse, varscan2
- MPP3 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 260/540 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs201741713; called by muse, mutect2, varscan2
- MRC2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 325/669 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.38); catalogued as rs370889422, COSV57643896; called by muse, mutect2, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 112/247 reads (45%) | catalogued as rs757691558; called by mutect2, varscan2
- MROH7 | c.2482G>A p.V828I | Missense Mutation (SNP) | VAF 210/428 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs367669775; called by muse, mutect2, varscan2
- MRPL28 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 69/354 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs748605681; called by muse, mutect2, varscan2
- MS4A10 | c.736A>G p.K246E | Missense Mutation (SNP) | VAF 178/348 reads (51%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1477703782; called by muse, varscan2
- MSANTD2 | c.869C>A p.S290* (on ENST00000374979 / NM_001308027.2; = p.S238* on NM_024631.4) | Nonsense Mutation (SNP) | VAF 143/306 reads (47%) | catalogued as COSV53447335; called by muse, mutect2, varscan2
- MTHFD2L | c.1033del p.I345Sfs*48 (on ENST00000395759 / NM_001144978.2; = p.I287Sfs*48 on NM_001004346.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 41/302 reads (14%) | catalogued as rs761538540; called by mutect2, pindel, varscan2
- MUC16 | c.40394C>T p.P13465L | Missense Mutation (SNP) | VAF 30/522 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.993); catalogued as COSV66690835; called by muse, mutect2
- MYBBP1A | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 283/638 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs201621567; called by muse, mutect2, varscan2
- MYBPC3 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 267/608 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as rs370362589, COSV57023270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYCBP2 | c.7876G>A p.G2626R (on ENST00000357337; = p.G2664R on NM_015057.5) | Missense Mutation (SNP) | VAF 147/300 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs917350267, COSV62012411; called by muse, mutect2, varscan2
- MYH11 | c.5329C>T p.R1777C | Missense Mutation (SNP) | VAF 292/620 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1441546016, COSV55542564, COSV55564570; called by muse, mutect2, varscan2
- MYH6 | c.5644C>T p.R1882C | Missense Mutation (SNP) | VAF 126/289 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs779397173; called by muse, mutect2, varscan2
- MYNN | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1320938484; called by muse, mutect2, varscan2
- MYO10 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 44/512 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as rs74389230, COSV72563266; called by muse, mutect2
- MYO1D | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59012061; called by muse, mutect2
- MYO1G | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 38/594 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1195429620; called by muse, mutect2
- MYO9B | c.2560C>T p.R854C | Missense Mutation (SNP) | VAF 171/344 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs1261872111, COSV68283164; called by muse, mutect2, varscan2
- NASP | c.478del p.T160Qfs*29 | Frame Shift Del (DEL) | VAF 106/496 reads (21%) | catalogued as COSV100601638; called by mutect2, pindel, varscan2
- NBPF11 | c.1807C>T p.R603W | Missense Mutation (SNP) | VAF 77/445 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.135); catalogued as rs1300483601; called by muse, mutect2, varscan2
- NCKAP5 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 134/311 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs776055565, COSV58427529; called by muse, mutect2
- NCLN | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 315/673 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs1480880606; called by muse, mutect2, varscan2
- NCOR2 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 48/542 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867064743; called by muse, mutect2
- NCR3 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 52/1024 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs749689798; called by muse, mutect2
- NDC80 | c.1889A>G p.Y630C | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1268736007, COSV55249251; called by muse, varscan2
- NELFA | c.1568C>T p.T523M (on ENST00000542778; = p.T512M on NM_005663.5) | Missense Mutation (SNP) | VAF 240/521 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200742495; called by muse, mutect2, varscan2
- NIM1K | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 161/376 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as rs761768735; called by muse, mutect2, varscan2
- NKX2-2 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 135/264 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV65819993; called by muse, mutect2, varscan2
- NLRP1 | c.3338C>T p.T1113M | Missense Mutation (SNP) | VAF 154/359 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs761505501, CM1212938; called by muse, mutect2, varscan2
- NLRP1 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 128/303 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs201312429, COSV52559301; called by muse, mutect2, varscan2
- NLRP12 | c.1027del p.R343Gfs*49 | Frame Shift Del (DEL) | VAF 178/428 reads (42%) | catalogued as COSV100145574; called by mutect2, pindel, varscan2
- NLRP2 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 303/579 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.951); catalogued as rs1473452983, COSV54751859, COSV54752546; called by muse, mutect2, varscan2
- NLRP5 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 253/545 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs746597574, COSV101174046, COSV66761996; called by muse, mutect2, varscan2
- NLRX1 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 116/611 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.082); catalogued as rs1375367613; called by muse, mutect2, varscan2
- NOC2L | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 38/431 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs763357220; called by muse, mutect2
- NOL4 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 178/364 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763005568, COSV52348168; called by muse, mutect2, varscan2
- NOTCH2 | c.5153G>A p.R1718H | Missense Mutation (SNP) | VAF 278/525 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs774915799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH3 | c.1771T>C p.C591R | Missense Mutation (SNP) | VAF 106/972 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM125164; called by muse, mutect2, varscan2
- NOTCH4 | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 56/643 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100900964; called by muse, mutect2
- NOTO | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 171/706 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs745707352; called by muse, mutect2, varscan2
- NPAT | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs546214038; called by muse, mutect2
- NPY1R | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 114/238 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as rs375717997, COSV99649120; called by muse, mutect2, varscan2
- NRCAM | c.1333G>A p.A445T (on ENST00000379028 / NM_001371124.1; = p.A439T on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/138 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs1319574637, COSV100694448; called by muse, mutect2, varscan2
- NRXN1 | c.3748G>A p.A1250T | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.691); catalogued as rs758023224; called by muse, mutect2, varscan2
- NRXN1 | c.471dup p.L158Afs*29 | Frame Shift Ins (INS) | VAF 284/408 reads (70%) | catalogued as rs774889610; called by mutect2, pindel, varscan2
- NRXN2 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 336/663 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs200169230, COSV55452927, COSV99634427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NTN1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 340/692 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1236907234; called by muse, mutect2, varscan2
- NTSR2 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 285/582 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs1461394810, COSV60990387; called by muse, mutect2, varscan2
- NUBP2 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 390/816 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs763720154; called by muse, varscan2
- NWD1 | c.2251G>T p.G751C | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV104410674, COSV60337883; called by muse, mutect2, varscan2
- NXPE3 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 136/320 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs775332489; called by muse, mutect2, varscan2
- NYAP2 | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 326/678 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as rs907521109, COSV56011683; called by muse, mutect2, varscan2
- OAS1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 287/634 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1021340095, COSV52534554, COSV52536141; called by muse, mutect2, varscan2
- OCEL1 | c.619_621del p.X207_splice | Splice Site (DEL) | VAF 88/237 reads (37%) | catalogued as rs777033417; called by mutect2, pindel, varscan2
- ONECUT3 | c.1448del p.G483Afs*128 | Frame Shift Del (DEL) | VAF 207/426 reads (49%) | catalogued as rs1568603892, COSV66639731; called by mutect2, pindel, varscan2
- OR10C1 | c.661C>T p.R221C (on ENST00000622521; = p.R219C on NM_013941.3) | Missense Mutation (SNP) | VAF 396/802 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV65822599; called by muse, mutect2, varscan2
- OR14C36 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 143/350 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748003267; called by muse, mutect2, varscan2
- OR2G3 | c.186dup p.L63Sfs*14 | Frame Shift Ins (INS) | VAF 162/398 reads (41%) | catalogued as COSV60682833; called by mutect2, pindel, varscan2
- OR4C6 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.111); catalogued as COSV58602805, COSV58603641; called by muse, mutect2, varscan2
- OR5P2 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 206/398 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs747026044; called by muse, mutect2, varscan2
- OR8G5 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 166/356 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.664); catalogued as rs148046413, COSV58383102; called by muse, mutect2, varscan2
- ORC3 | c.610del p.R204Gfs*16 | Frame Shift Del (DEL) | VAF 154/296 reads (52%) | catalogued as rs1336736903; called by mutect2, varscan2
- OTOF | c.3553G>A p.V1185I (on ENST00000272371 / NM_194248.3; = p.V438I on NM_004802.4) | Missense Mutation (SNP) | VAF 143/300 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.513); catalogued as rs766090648, COSV55498627, COSV55523439; called by muse, mutect2, varscan2
- OTULIN | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 108/489 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs756345508; called by muse, mutect2, varscan2
- OXTR | c.700A>G p.K234E | Missense Mutation (SNP) | VAF 330/708 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs184175311; called by muse, mutect2, varscan2
- P2RX4 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 261/497 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs566926483, COSV61502320; called by muse, mutect2, varscan2
- P2RY6 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 72/899 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs569014304, COSV62936543; called by muse, mutect2
- PADI3 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 180/411 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100968587, COSV64934333; called by muse, mutect2, varscan2
- PAEP | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 150/357 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs750586274; called by muse, mutect2, varscan2
- PAK6 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 27/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780508332; called by muse, mutect2
- PAMR1 | c.302dup p.T102Yfs*4 | Frame Shift Ins (INS) | VAF 150/360 reads (42%) | catalogued as rs751755759; called by mutect2, varscan2
- PAPLN | c.731G>A p.R244Q (on ENST00000554301; = p.R217Q on NM_173462.4) | Missense Mutation (SNP) | VAF 320/692 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs930891145, COSV53717566; called by muse, mutect2, varscan2
- PARD3B | c.3006G>T p.K1002N (on ENST00000406610 / NM_001302769.2; = p.K933N on NM_057177.7) | Missense Mutation (SNP) | VAF 142/297 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs779244384, COSV100595784; called by muse, mutect2, varscan2
- PARP11 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 111/279 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs762146923, COSV57393424; called by muse, mutect2, varscan2
- PASK | c.2431C>T p.R811* | Nonsense Mutation (SNP) | VAF 290/578 reads (50%) | catalogued as rs776234374, COSV52158022; called by muse, mutect2, varscan2
- PBRM1 | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 82/206 reads (40%) | catalogued as COSV56260075; called by muse, mutect2, varscan2
- PBRM1 | c.835del p.I279Yfs*4 | Frame Shift Del (DEL) | VAF 84/233 reads (36%) | catalogued as rs771618422; called by mutect2, pindel, varscan2
- PCDH17 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 41/676 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781536747, COSV64973090; called by muse, mutect2
- PCDHB11 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 454/1055 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); catalogued as rs782123077, COSV61311634; called by muse, mutect2, varscan2
- PCDHB12 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 100/465 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); catalogued as rs781803373, COSV53396047; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 84/194 reads (43%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCSK5 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 182/385 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65083440; called by muse, mutect2, varscan2
- PCSK9 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 88/475 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs763487412; called by muse, mutect2, varscan2
- PDGFB | c.657dup p.K220Qfs*12 | Frame Shift Ins (INS) | VAF 148/733 reads (20%) | catalogued as rs1274478632; called by mutect2, pindel, varscan2
- PDK4 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs199786522, COSV50012954; called by muse, mutect2
- PDZD8 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 151/302 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as rs150304837; called by muse, mutect2, varscan2
- PEAR1 | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 372/850 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs746523616; called by muse, mutect2
- PECR | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 112/298 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773331067; called by muse, mutect2
- PEG10 | c.974T>C p.L325P (on ENST00000482108 / NM_001040152.2; = p.A358= on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 239/539 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV71788280; called by muse, mutect2, varscan2
- PERM1 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 354/754 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as rs937415720, COSV58021013; called by muse, mutect2, varscan2
- PEX14 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 154/306 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs540190684, COSV100750156; called by muse, mutect2, varscan2
- PFDN6 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 173/332 reads (52%) | catalogued as COSV101004823; called by muse, mutect2, varscan2
- PFKFB2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 137/332 reads (41%) | PolyPhen probably damaging (0.988); catalogued as rs1335499341, COSV65548814; called by muse, mutect2, varscan2
- PGAP2 | c.755A>G p.K252R (on ENST00000463452 / NM_001346398.2; = p.K313R on NM_014489.4) | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as rs761992792; called by muse, mutect2, varscan2
- PHF10 | c.1441G>C p.A481P | Missense Mutation (SNP) | VAF 176/421 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs780408412; called by muse, mutect2, varscan2
- PHLDB1 | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 45/685 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs782138733, COSV61876454; called by muse, mutect2
- PIBF1 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 78/198 reads (39%) | catalogued as rs751280996; called by muse, varscan2
- PIGQ | c.1462G>A p.V488M | Missense Mutation (SNP) | VAF 231/505 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as rs1206255851; called by muse, mutect2, varscan2
- PIK3CA | c.3013A>G p.M1005V | Missense Mutation (SNP) | VAF 222/454 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV55934947; called by muse, mutect2, varscan2
- PIP5K1C | c.372del p.A125Pfs*40 | Frame Shift Del (DEL) | VAF 153/409 reads (37%) | catalogued as COSV58952604; called by mutect2, pindel, varscan2
- PITPNM1 | c.2792G>A p.R931H | Missense Mutation (SNP) | VAF 289/649 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as rs577684030, COSV99653776; called by muse, mutect2, varscan2
- PKD1L3 | c.3956C>T p.S1319L | Missense Mutation (SNP) | VAF 159/333 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs775716960; called by muse, mutect2, varscan2
- PKP3 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.328); catalogued as rs777411352; called by muse, mutect2
- PLA2G15 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 157/349 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as rs140788278; called by muse, mutect2, varscan2
- PLA2G4D | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 279/587 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs777540857; called by muse, mutect2, varscan2
- PLA2G6 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 132/310 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs372511574, COSV59269810; called by muse, mutect2, varscan2
- PLCB4 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 95/229 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs762218499; called by muse, varscan2
- PLCD3 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 178/334 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs752360452, COSV59559042; called by muse, varscan2
- PLCH1 | c.2726G>A p.R909Q (on ENST00000340059 / NM_001130960.2; = p.R901Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 214/478 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs541279759, COSV58208981; called by muse, mutect2, varscan2
- PLEKHD1 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 58/749 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1318117307; called by muse, mutect2
- PLEKHG4 | c.3091G>A p.V1031I | Missense Mutation (SNP) | VAF 184/379 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs776052745; called by muse, mutect2, varscan2
- PLIN1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 206/486 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs375328191; called by muse, mutect2, varscan2
- PLSCR1 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 167/349 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.178); catalogued as rs754532375; called by muse, mutect2, varscan2
- PLXNA3 | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 39/321 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs998664047, COSV63753267; called by muse, mutect2, varscan2
- PLXND1 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 445/840 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV60712409; called by muse, mutect2, varscan2
- PMEL | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 98/539 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs750057934, COSV59384289; called by muse, mutect2, varscan2
- PNMA1 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 128/525 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs952459622; called by muse, mutect2, varscan2
- POLQ | c.5857C>T p.R1953* | Nonsense Mutation (SNP) | VAF 168/386 reads (44%) | catalogued as rs150312701; called by muse, varscan2
- POLR3E | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 167/333 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755707764, COSV100241924; called by muse, mutect2, varscan2
- POMT1 | c.1730C>T p.T577I | Missense Mutation (SNP) | VAF 164/389 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.567); catalogued as rs1564384031; called by muse, mutect2, varscan2
- POR | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 39/428 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782772517; called by muse, mutect2, varscan2
- POTEE | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 279/630 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1390475550, COSV58232713; called by muse, mutect2, varscan2
- PPM1H | c.844T>C p.Y282H | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1286806690; called by muse, mutect2, varscan2
- PPP1R9A | c.2387A>G p.E796G | Missense Mutation (SNP) | VAF 115/287 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56902855; called by muse, mutect2, varscan2
- PRDX6 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 150/296 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs1019938578, COSV100458359; called by muse, mutect2, varscan2
- PRKCH | c.1293dup p.V432Cfs*9 | Frame Shift Ins (INS) | VAF 153/378 reads (40%) | catalogued as rs772764842; called by mutect2, pindel, varscan2
- PRKD2 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 76/494 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as rs369442988; called by muse, mutect2, varscan2
- PROKR1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 249/496 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs200238619, COSV58137151; called by muse, mutect2, varscan2
- PROKR1 | c.879del p.Y293* | Frame Shift Del (DEL) | VAF 216/585 reads (37%) | catalogued as COSV58136533; called by mutect2, pindel, varscan2
- PRR12 | c.59C>T p.P20L (on ENST00000615927; = p.P841L on NM_020719.3) | Missense Mutation (SNP) | VAF 343/666 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.84); catalogued as rs766777377; called by mutect2, varscan2
- PRR22 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 362/743 reads (49%) | catalogued as rs1470172044; called by muse, mutect2, varscan2
- PRRC2B | c.6341C>T p.P2114L | Missense Mutation (SNP) | VAF 51/548 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs759055475, COSV57644666; called by muse, mutect2
- PSD2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 369/767 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs762173979, COSV51199797; called by muse, mutect2, varscan2
- PTAFR | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 241/515 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs749761557; called by muse, mutect2, varscan2
- PTPN4 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55310509, COSV99751845; called by muse, varscan2
- PTPRS | c.4069C>T p.L1357F | Missense Mutation (SNP) | VAF 24/636 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.11); catalogued as rs1469959251; called by muse, mutect2
- PTPRS | c.3838G>A p.E1280K | Missense Mutation (SNP) | VAF 57/753 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs757905971, COSV53640044; called by muse, mutect2
- PTPRU | c.4009C>T p.R1337W | Missense Mutation (SNP) | VAF 205/443 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs996914255, COSV100113982; called by muse, mutect2, varscan2
- PXDN | c.1772G>C p.R591P | Missense Mutation (SNP) | VAF 208/497 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53228140; called by muse, mutect2, varscan2
- PYGM | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 364/776 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs758774720; called by muse, mutect2, varscan2
- PYROXD2 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 240/546 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs763571324; called by muse, mutect2, varscan2
- RAD52 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 127/596 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs768836719, COSV57275008; called by muse, mutect2, varscan2
- RALGPS1 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 95/276 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs756319072; called by muse, mutect2, varscan2
- RAP1GAP | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 99/356 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as rs1267192630, COSV99264851; called by muse, mutect2, varscan2
- RAPSN | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 275/603 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.023); catalogued as rs150756111, COSV54085516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RASA3 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 122/293 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766568683, COSV100481049; called by muse, mutect2, varscan2
- RASEF | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 139/267 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749465225, COSV64587507; called by muse, mutect2, varscan2
- RASGEF1C | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 21/677 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1400239312; called by muse, mutect2
- RASSF2 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 276/528 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs751465589; called by muse, mutect2, varscan2
- RBBP8 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 54/548 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs996855677; called by muse, mutect2
- RBM12B | c.2303del p.P768Qfs*119 | Frame Shift Del (DEL) | VAF 183/850 reads (22%) | catalogued as COSV67897551; called by mutect2, pindel, varscan2
- RBM12B | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 128/739 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as rs772380709, COSV67898875; called by muse, mutect2, varscan2
- RBM44 | c.112dup p.I38Nfs*44 (on ENST00000611254; = p.I672Nfs*44 on NM_001080504.2) | Frame Shift Ins (INS) | VAF 161/428 reads (38%) | catalogued as rs777249522; called by mutect2, pindel, varscan2
- RBM47 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 332/674 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.466); catalogued as rs747390984, COSV55933085; called by muse, mutect2, varscan2
- RDH11 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 187/381 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs752811983; called by muse, varscan2
- RECQL4 | c.1166_1167del p.C389Ffs*33 | Frame Shift Del (DEL) | VAF 221/603 reads (37%) | catalogued as rs34134064; called by pindel, varscan2
- RELCH | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 136/297 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1327513368; called by muse, mutect2, varscan2
- RELL1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 79/482 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.09); catalogued as COSV58450396, COSV58452382; called by muse, mutect2, varscan2
- RFXANK | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 159/364 reads (44%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as rs562901844, COSV57393055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGS9BP | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 194/848 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100043093; called by muse, varscan2
- RHBDL1 | c.1282G>A p.D428N (on ENST00000219551 / NM_001318733.2; = p.D363N on NM_001278720.2) | Missense Mutation (SNP) | VAF 270/581 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1331496412; called by muse, mutect2, varscan2
- RHOT2 | c.1562_1563del p.F521Cfs*173 | Frame Shift Del (DEL) | VAF 191/492 reads (39%) | catalogued as rs757860727; called by mutect2, pindel, varscan2
- RIMS2 | c.1022G>A p.R341H (on ENST00000666250 / NM_001348490.2; = p.R149H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 113/575 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1459469823, COSV51696368, COSV99158649; called by muse, mutect2, varscan2
- RMND5B | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 199/395 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs771814384; called by muse, mutect2, varscan2
- RNF111 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 198/446 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as rs757470859, COSV62088105; called by muse, mutect2
- RNF112 | c.1693G>A p.V565M | Missense Mutation (SNP) | VAF 395/822 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as rs1403627879; called by muse, mutect2, varscan2
- RNF122 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 138/266 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs773808716; called by muse, mutect2, varscan2
- RNF212B | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 153/297 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as rs1408189492; called by muse, mutect2, varscan2
- RNF5 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 306/673 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780921402; called by muse, mutect2, varscan2
- RNF5 | c.526del p.W176Gfs*22 | Frame Shift Del (DEL) | VAF 64/662 reads (10%) | catalogued as rs758165894; called by mutect2, pindel
- RNLS | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 177/398 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59293935, COSV59298454; called by muse, mutect2, varscan2
- RPL22L1 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 126/347 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs555361307; called by muse, mutect2, varscan2
- RPL23 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV55560380; called by muse, mutect2, varscan2
- RPS6KA2 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 96/561 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1223838046, COSV55816243; called by muse, mutect2
- RPS6KA4 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 206/411 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.457); catalogued as rs1268525057; called by muse, mutect2, varscan2
- RPTOR | c.2362C>T p.R788C | Missense Mutation (SNP) | VAF 254/576 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.795); catalogued as rs781190662, COSV60811595; called by muse, mutect2, varscan2
- RRAGC | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 106/466 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs770232749, COSV104426254; called by muse, mutect2, varscan2
- RREB1 | c.4280G>A p.G1427D | Missense Mutation (SNP) | VAF 310/685 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1303483520; called by muse, mutect2, varscan2
- RSF1 | c.2888G>A p.R963H | Missense Mutation (SNP) | VAF 131/301 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57836020; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 93/195 reads (48%) | catalogued as rs759252078; called by mutect2, varscan2
- RUBCNL | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 196/433 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs764655857, COSV100528893; called by muse, mutect2, varscan2
- RYBP | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 184/376 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV72180911; called by muse, mutect2, varscan2
- RYR2 | c.1397del p.P466Qfs*5 | Frame Shift Del (DEL) | VAF 203/469 reads (43%) | catalogued as COSV100771204; called by mutect2, pindel, varscan2
- SACS | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 195/443 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs1376756373, COSV66542921; called by muse, mutect2, varscan2
- SALL4 | c.2492G>A p.R831Q | Missense Mutation (SNP) | VAF 159/337 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as rs995868253; called by muse, mutect2, varscan2
- SATB2 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 98/454 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99613075; called by muse, mutect2, varscan2
- SCAP | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 177/394 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as rs147885193; called by muse, mutect2, varscan2
- SCAPER | c.2613del p.A872Pfs*4 | Frame Shift Del (DEL) | VAF 136/312 reads (44%) | catalogued as rs757259031; called by mutect2, varscan2
- SCAPER | c.2179C>T p.R727* | Nonsense Mutation (SNP) | VAF 121/259 reads (47%) | catalogued as rs978336151, COSV57748830; called by muse, mutect2, varscan2
- SCN8A | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 183/369 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs928008352; called by muse, mutect2, varscan2
- SDK1 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 93/517 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs375595635; called by muse, mutect2, varscan2
- SDK2 | c.5030C>T p.T1677M | Missense Mutation (SNP) | VAF 200/452 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs772454614; called by muse, varscan2
- SDR9C7 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 282/610 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs749798308; called by muse, mutect2, varscan2
- SEC24C | c.2921G>A p.R974H | Missense Mutation (SNP) | VAF 80/395 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs777676193; called by muse, mutect2, varscan2
- SELENOI | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 160/366 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs933233143, COSV53144950; called by muse, mutect2, varscan2
- SEMA6B | c.826del p.R276Afs*11 | Frame Shift Del (DEL) | VAF 407/947 reads (43%) | catalogued as rs781437207, COSV56702141, COSV56702780; called by mutect2, pindel, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 42/236 reads (18%) | catalogued as rs750651342; called by mutect2, varscan2
- SEPTIN12 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 157/381 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.509); catalogued as rs201646631; called by muse, mutect2, varscan2
- SERAC1 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 118/309 reads (38%) | catalogued as rs780182065, COSV65597875; called by muse, mutect2, varscan2
- SERPINB7 | c.309del p.F103Lfs*33 | Frame Shift Del (DEL) | VAF 85/235 reads (36%) | catalogued as rs757235730, COSV100321048; called by mutect2, pindel, varscan2
- SETD1A | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 70/740 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs764354827, COSV99354043; called by muse, mutect2
- SETDB1 | c.2782C>T p.R928W | Missense Mutation (SNP) | VAF 274/568 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746536604, COSV54993957; called by muse, mutect2, varscan2
- SETDB2 | c.2152del p.I718Yfs*11 | Frame Shift Del (DEL) | VAF 104/208 reads (50%) | catalogued as rs775302281, COSV57902985; called by mutect2, varscan2
- SFI1 | c.1402C>T p.R468W (on ENST00000400288 / NM_001007467.3; = p.R437W on NM_014775.4) | Missense Mutation (SNP) | VAF 146/298 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs768628316, COSV66291567; called by muse, mutect2, varscan2
- SH2B3 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 240/531 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.194); catalogued as rs374931521, COSV57983869; called by muse, mutect2, varscan2
- SHANK3 | c.4317G>T p.Q1439H | Missense Mutation (SNP) | VAF 79/730 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV53186128; called by muse, mutect2, varscan2
- SHC2 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1489431473, COSV52750271; called by muse, mutect2, varscan2
- SHF | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 283/661 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs758587603; called by muse, mutect2, varscan2
- SHKBP1 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 331/677 reads (49%) | catalogued as rs757844991; called by muse, mutect2, varscan2
- SHMT1 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 120/292 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as rs1262762031; called by muse, mutect2, varscan2
- SHMT1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 172/356 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766011995, COSV57399716; called by muse, varscan2
- SHMT2 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 236/497 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs145565217; called by muse, varscan2
- SIAE | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 46/515 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1330050477, COSV55016145; called by muse, mutect2
- SIGLEC1 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 366/779 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.327); catalogued as rs756452334, COSV52474008, COSV99171436; called by muse, mutect2, varscan2
- SIGLEC10 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 200/412 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752669777, COSV59482170; called by muse, mutect2, varscan2
- SIM2 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 342/696 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs766072259; called by muse, mutect2, varscan2
- SKIDA1 | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 147/324 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV71610447; called by muse, mutect2, varscan2
- SLAIN2 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 190/401 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs771548777; called by muse, mutect2, varscan2
- SLC11A1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 127/282 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs375958099; called by muse, mutect2, varscan2
- SLC13A5 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 217/465 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs759069275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC22A13 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 162/354 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs749485018; called by muse, mutect2, varscan2
- SLC22A15 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 154/346 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.38); catalogued as rs552602518, COSV65677496; called by muse, mutect2, varscan2
- SLC22A25 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 243/507 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs762029744, COSV100123860; called by muse, mutect2, varscan2
- SLC25A10 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 283/570 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772338324, COSV58970218; called by muse, mutect2, varscan2
- SLC2A5 | c.1247dup p.S417Qfs*64 | Frame Shift Ins (INS) | VAF 189/490 reads (39%) | catalogued as rs1223118492; called by mutect2, pindel, varscan2
- SLC35E4 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 123/645 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs771540555; called by muse, mutect2, varscan2
- SLC38A10 | c.2527A>G p.R843G | Missense Mutation (SNP) | VAF 120/654 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs762505329; called by mutect2, varscan2
- SLC43A1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 224/491 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as rs1169516760, COSV53558881; called by muse, mutect2, varscan2
- SLC46A3 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs201296960, COSV99906557; called by muse, mutect2, varscan2
- SLC4A10 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 155/377 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55772749; called by muse, mutect2, varscan2
- SLC6A4 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 252/528 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.29); catalogued as rs1250876597; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2223del p.F741Lfs*13 (on ENST00000540229 / NM_001371097.1; = p.F680Lfs*13 on NM_001009562.4) | Frame Shift Del (DEL) | VAF 22/160 reads (14%) | catalogued as COSV67441233; called by mutect2, pindel, varscan2
- SMAP1 | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 98/238 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.53); catalogued as rs1384623633; called by muse, mutect2, varscan2
- SMCP | c.175T>G p.C59G | Missense Mutation (SNP) | VAF 30/849 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs1307478178; called by muse, mutect2
- SMG1 | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 64/370 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1345051797; called by muse, mutect2, varscan2
- SMG5 | c.2329G>A p.A777T | Missense Mutation (SNP) | VAF 200/433 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs151243707; called by muse, mutect2, varscan2
- SMO | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 256/518 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs761395599, COSV50824306; called by muse, mutect2, varscan2
- SMOC2 | c.800G>A p.R267H (on ENST00000356284 / NM_001166412.2; = p.R278H on NM_022138.3) | Missense Mutation (SNP) | VAF 212/432 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs199557237; called by muse, mutect2, varscan2
- SMPD3 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 61/631 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); catalogued as rs757669112; called by muse, mutect2
- SMTN | c.1605del p.S536Vfs*33 | Frame Shift Del (DEL) | VAF 224/484 reads (46%) | catalogued as rs758895137; called by mutect2, varscan2
- SMTNL2 | c.1372C>T p.R458C (on ENST00000389313 / NM_001114974.2; = p.R314C on NM_198501.3) | Missense Mutation (SNP) | VAF 159/326 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1052710386, COSV58810028; called by muse, mutect2, varscan2
- SOGA1 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 286/603 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs897979650; called by muse, mutect2, varscan2
- SORCS1 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 186/390 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs776564036, COSV53855107, COSV53858639, COSV99550093; called by muse, mutect2, varscan2
- SORCS2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 157/322 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs371760048; called by muse, mutect2, varscan2
- SORL1 | c.2128T>C p.Y710H | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV52754951; called by muse, mutect2, varscan2
- SP8 | c.1149G>T p.E383D (on ENST00000361443 / NM_198956.4; = p.E401D on NM_182700.6) | Missense Mutation (SNP) | VAF 274/609 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100815403; called by muse, varscan2
- SPAG17 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100308966; called by muse, mutect2, varscan2
- SPATA19 | c.78G>A p.S26= | Splice Region (SNP) | VAF 28/450 reads (6%) | catalogued as rs749085507, COSV54483498; called by muse, mutect2
- SPATA7 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 248/530 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs753250204, COSV50416166; called by muse, mutect2, varscan2
- SPATC1 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 242/512 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs138012879; called by muse, mutect2, varscan2
- SPEN | c.7390G>A p.D2464N | Missense Mutation (SNP) | VAF 348/736 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.972); catalogued as rs1185220287, COSV65367471; called by muse, mutect2, varscan2
- SPG21 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 156/390 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.342); catalogued as rs778148078, COSV52604132; called by muse, varscan2
- SPTB | c.4454G>A p.R1485Q | Missense Mutation (SNP) | VAF 34/357 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs140697785, COSV67633036; called by muse, mutect2
- SRCAP | c.3875C>T p.P1292L | Missense Mutation (SNP) | VAF 229/463 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as rs1436128390; called by muse, mutect2, varscan2
- SREBF1 | c.405del p.T136Pfs*28 | Frame Shift Del (DEL) | VAF 142/913 reads (16%) | catalogued as COSV55420292; called by mutect2, pindel, varscan2
- SRPK3 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 71/326 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.639); catalogued as rs782480986; called by muse, varscan2
- ST3GAL6 | c.517dup p.S173Ffs*7 | Frame Shift Ins (INS) | VAF 56/403 reads (14%) | catalogued as rs757665003; called by mutect2, pindel, varscan2
- ST6GAL2 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 136/302 reads (45%) | PolyPhen benign (0.34); catalogued as rs371333085; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 90/232 reads (39%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAC | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs769980894, COSV56213071; called by muse, mutect2, varscan2
- STARD4 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 98/241 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs765122675, COSV56968070; called by muse, mutect2, varscan2
- STARD9 | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 282/606 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.046); catalogued as COSV51901993; called by muse, mutect2, varscan2
- STIL | c.224del p.N75Ifs*10 | Frame Shift Del (DEL) | VAF 120/262 reads (46%) | catalogued as rs769117150; called by mutect2, varscan2
- STOX2 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 50/546 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs746138201; called by muse, mutect2
- STRAP | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs999690976; called by muse, mutect2, varscan2
- STXBP2 | c.249G>A p.S83= | Splice Region (SNP) | VAF 178/388 reads (46%) | catalogued as rs1374023769, COSV99656995; ClinVar: uncertain significance; called by muse, varscan2
- SUPT5H | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 60/359 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs746130381, COSV63238399; called by muse, mutect2, varscan2
- SV2B | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 145/347 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs146788122; called by muse, mutect2, varscan2
- SYNGAP1 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 393/842 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1356491362; called by muse, mutect2, varscan2
- SYNPO2L | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 195/449 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763467865, COSV100866455; called by muse, mutect2, varscan2
- SYT5 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 249/515 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374784329; called by muse, mutect2, varscan2
- TACC2 | c.6646C>T p.P2216S (on ENST00000334433; = p.P294S on NM_006997.4) | Missense Mutation (SNP) | VAF 42/690 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.052); catalogued as rs1434010762; called by muse, mutect2
- TACC2 | c.7147A>G p.T2383A (on ENST00000334433; = p.T461A on NM_006997.4) | Missense Mutation (SNP) | VAF 121/613 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs1421786447; called by muse, mutect2, varscan2
- TAF11L12 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 119/247 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1170640191; called by muse, mutect2, varscan2
- TAF12 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 86/448 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1373155792; called by muse, mutect2, varscan2
- TAF15 | c.1115G>A p.R372Q (on ENST00000605844 / NM_139215.3; = p.R369Q on NM_003487.4) | Missense Mutation (SNP) | VAF 167/368 reads (45%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.991); catalogued as rs765087079; called by muse, mutect2, varscan2
1,357 further variants in this file (757 protein-altering or splice-affecting, 518 silent, 82 other) are not listed here.
